Somatic mutation profile of tumor specimen TCGA-A7-A0CG-01A (aliquot TCGA-A7-A0CG-01A-11W-A019-09) from TCGA case TCGA-A7-A0CG, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.3 years (28,596 days).
Specimen TCGA-A7-A0CG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fc40b8a-c54d-4ce3-ba57-94261860a21c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A0CG-10A (Blood Derived Normal), aliquot TCGA-A7-A0CG-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b70d74d2-72d9-405c-bde7-bb6a077d7a6b

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 31, Silent 15, Nonsense Mutation 3, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF4 | c.1225A>C p.K409Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV65928521; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 80/383 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARAP2 | c.1272T>A p.S424R | Missense Mutation (SNP) | VAF 96/558 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.942); catalogued as COSV58287738; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2299C>G p.L767V | Missense Mutation (SNP) | VAF 85/431 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV59476746; called by muse, mutect2, varscan2
- ATXN3L | c.1042A>T p.N348Y | Missense Mutation (SNP) | VAF 96/504 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as COSV66075812; called by muse, mutect2, varscan2
- B3GAT2 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445262803, COSV57771511; called by muse, mutect2, varscan2
- C4BPA | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 26/810 reads (3%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as rs868450380, COSV100891243; called by muse, mutect2
- CFH | c.1566C>A p.D522E | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV66409360; called by muse, mutect2, varscan2
- CSMD2 | c.3929T>C p.I1310T | Missense Mutation (SNP) | VAF 88/466 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs564264462, COSV99592504; called by muse, mutect2
- CXorf58 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as COSV64858350; called by muse, mutect2, varscan2
- DNTT | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as rs752907059, COSV100960506, COSV64523040; called by muse, mutect2, varscan2
- FAM47C | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1556332120, COSV100792984, COSV63726021; called by muse, mutect2, varscan2
- FGF14 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101086982; called by muse, mutect2
- FGF7 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 72/367 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51066217; called by muse, mutect2, varscan2
- FMN2 | c.2377C>T p.R793* | Nonsense Mutation (SNP) | VAF 15/189 reads (8%) | catalogued as rs780928554, COSV60425069; called by muse, mutect2
- FMR1NB | c.714G>C p.K238N | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.15); catalogued as COSV65072618; called by muse, mutect2
- GABBR2 | c.1450A>C p.I484L | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99410737; called by muse, mutect2
- GANC | c.949A>G p.R317G | Missense Mutation (SNP) | VAF 80/422 reads (19%) | PolyPhen benign (0); catalogued as COSV58809444; called by muse, mutect2, varscan2
- GUCA1A | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs186171388, COSV50005518; called by muse, mutect2, varscan2
- LYVE1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs758069812, COSV56282814; called by muse, mutect2, varscan2
- MADD | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60621209; called by muse, mutect2, varscan2
- MYBL1 | c.1093A>C p.I365L | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as COSV101576576; called by muse, mutect2
- MYO5B | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs770761011, COSV53220786; called by muse, mutect2, varscan2
- OR1L4 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 26/628 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV52340104, COSV99413917; called by muse, mutect2
- PPP1R3F | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV99278900; called by muse, mutect2
- PRKAB1 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs375579154; called by muse, mutect2, varscan2
- RTL4 | c.636C>A p.C212* | Nonsense Mutation (SNP) | VAF 185/980 reads (19%) | catalogued as COSV61206174, COSV61206647; called by muse, mutect2, varscan2
- SETD4 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as COSV100145686; called by muse, mutect2
- SYNE1 | c.595G>C p.E199Q (on ENST00000367255 / NM_182961.4; = p.E206Q on NM_033071.3) | Missense Mutation (SNP) | VAF 10/332 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV99572190; called by muse, mutect2
- TET1 | c.4185T>A p.F1395L | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV101018566; called by muse, mutect2
- TRPC3 | c.785C>T p.P262L (on ENST00000379645 / NM_001366479.2; = p.P189L on NM_003305.2) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571866879, COSV53377224; called by muse, mutect2, varscan2
- UPF3B | c.1049G>A p.R350Q (on ENST00000276201 / NM_080632.3; = p.R337Q on NM_023010.3) | Missense Mutation (SNP) | VAF 81/753 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as rs185347914, COSV99352276; called by muse, mutect2, varscan2
- WAS | c.777C>T p.D259= | Splice Region (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100939511; called by muse, mutect2
- WDR44 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 110/1238 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV99561750; called by muse, mutect2
- WNK1 | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 96/512 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756361196, COSV60035460; called by muse, mutect2, varscan2
- DDX28 | c.1427dup p.T477Nfs*40 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- ATM | c.1362T>C p.Y454= | Silent (SNP) | VAF 16/328 reads (5%) | catalogued as rs1373614735, COSV99590623; ClinVar: likely benign; called by muse, mutect2
- CORIN | c.2685C>T p.I895= | Silent (SNP) | VAF 22/264 reads (8%) | catalogued as rs140770758; called by muse, mutect2
- CXADR | c.534G>A p.L178= | Silent (SNP) | VAF 58/320 reads (18%) | catalogued as COSV53029462; called by muse, mutect2, varscan2
- DHDH | c.576G>A p.Q192= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV55483563; called by muse, mutect2
- EIF3B | c.1443C>T p.F481= | Silent (SNP) | VAF 132/467 reads (28%) | catalogued as rs1200358769, COSV62803633; called by muse, mutect2, varscan2
- FBXO24 | c.1644G>C p.L548= (on ENST00000241071 / NM_033506.3; = p.L586= on NM_012172.5) | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1562824336, COSV99575500; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.117G>A p.V39= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99880602; called by muse, mutect2
- GALNT6 | c.933C>T p.P311= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs751682648, COSV62542202, COSV62542435; called by muse, mutect2, varscan2
- IFT122 | c.2034C>T p.I678= (on ENST00000348417 / NM_052989.3; = p.I619= on NM_018262.4) | Silent (SNP) | VAF 14/390 reads (4%) | catalogued as COSV99959585; called by muse, mutect2
- LIPA | c.714G>A p.A238= | Silent (SNP) | VAF 94/547 reads (17%) | catalogued as rs139282720; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MAP4 | c.3222C>T p.L1074= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as rs1559765062, COSV99275807; called by muse, mutect2
- MARCHF11 | c.771C>A p.A257= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100198109, COSV60126949; called by muse, mutect2, varscan2
- NLRP14 | c.1662G>A p.L554= | Silent (SNP) | VAF 15/356 reads (4%) | catalogued as COSV100205212; called by muse, mutect2
- PAPOLB | c.870G>A p.E290= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV68201465; called by muse, mutect2, varscan2
- PTPRZ1 | c.5412G>A p.L1804= | Silent (SNP) | VAF 12/298 reads (4%) | catalogued as COSV101100496; called by muse, mutect2
